Somatic mutation profile of tumor specimen MP2PRT-PARIAX-TMP1-A (aliquot MP2PRT-PARIAX-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARIAX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,381 days).
Specimen MP2PRT-PARIAX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30d3b00f-30e8-45d1-a805-0a498c1973f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARIAX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARIAX-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46996da9-18a9-4aaa-9e52-4812c54a2971

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CES1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 130/532 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369300055, COSV100828554; called by muse, varscan2
- FGFR2 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV60639166; called by muse, mutect2, varscan2
- FN1 | c.2593G>A p.V865I | Missense Mutation (SNP) | VAF 189/437 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs372271954; called by muse, mutect2, varscan2
- OR52M1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 52/459 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs776180864, COSV100798622; called by muse, mutect2, varscan2
- PCMTD1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 19/472 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs967167545; called by muse, mutect2
- TEK | c.602C>T p.S201L | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs540914328, COSV66235022; called by muse, mutect2, varscan2
- ARHGAP21 | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 53/423 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DNAH8 | c.2821A>C p.T941P | Missense Mutation (SNP) | VAF 23/380 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- FBF1 | c.3015G>T p.Q1005H (on ENST00000586717; = p.Q1020H on NM_001319193.1) | Missense Mutation (SNP) | VAF 79/694 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GYG2 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 231/246 reads (94%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HDAC2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406870 ATTCA>G | Missense Mutation (DEL) | VAF 85/99 reads (86%) | called by pindel, varscan2*
- IGKV3D-11 | chr2:90173413 ins CGG | In Frame Ins (INS) | VAF 80/232 reads (34%) | called by mutect2, pindel, varscan2
- IGLV4-69 | c.328_359delinsCCTGAAC p.Y110Pfs*? | Frame Shift Del (DEL) | VAF 72/118 reads (61%) | called by pindel, varscan2*
- MYOZ3 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.202); called by muse, mutect2
- NIPBL | c.6754G>C p.D2252H | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- OR2J1 | c.836A>G p.Y279C | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR8I2 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- PNISR | c.2255C>G p.S752* | Nonsense Mutation (SNP) | VAF 19/198 reads (10%) | called by muse, mutect2
- PPARGC1A | c.201T>A p.N67K | Missense Mutation (SNP) | VAF 182/481 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SPICE1 | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM229A | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 48/882 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); called by muse, mutect2
- COL6A3 | c.4218G>A p.T1406= | Silent (SNP) | VAF 169/539 reads (31%) | catalogued as rs756249024, COSV55096502; called by muse, mutect2, varscan2
- DCAF8L2 | c.93G>T p.A31= | Silent (SNP) | VAF 21/377 reads (6%) | called by muse, mutect2
- LOXHD1 | c.6669C>T p.H2223= (on ENST00000642948; = p.H2161= on NM_144612.7) | Silent (SNP) | VAF 248/562 reads (44%) | catalogued as rs759690810, COSV56059965; called by muse, mutect2, varscan2
- VASN | c.450C>T p.L150= | Silent (SNP) | VAF 26/924 reads (3%) | called by muse, mutect2
